Somatic mutation profile of tumor specimen TCGA-F4-6703-01A (aliquot TCGA-F4-6703-01A-11D-1835-10) from TCGA case TCGA-F4-6703, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.7 years (23,644 days).
Specimen TCGA-F4-6703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8657c2c9-05b5-4ddd-a481-6447dfdfedb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6703-10A (Blood Derived Normal), aliquot TCGA-F4-6703-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ea37d59-7910-4644-93d2-61c1aaa4a528

The open-access MAF lists 478 somatic variants for this specimen: 375 protein-altering or splice-affecting, 97 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 272, Silent 97, Frame Shift Del 61, Nonsense Mutation 15, Frame Shift Ins 13, Splice Site 10, In Frame Del 3, RNA 3, Intron 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- B2M | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62562913, COSV62563197; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- GUSB | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as rs1053785648, CM970707, COSV59224348; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/156 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1036T>G p.Y346D | Missense Mutation (SNP) | VAF 40/334 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV100911453, COSV64310562; called by muse, mutect2, varscan2
- SERPINA1 | c.1130del p.L377* | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | catalogued as rs763023697; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL3 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100206928; called by muse, mutect2
- ABCG5 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53213888; called by muse, mutect2, varscan2
- AC092143.1 | c.2116C>A p.R706S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59247129, COSV59249552; called by muse, mutect2
- ACE | c.3308del p.P1103Qfs*69 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs1447215842; called by mutect2, pindel, varscan2
- ACE | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.872); catalogued as rs755506668, COSV52014225; called by muse, mutect2
- ACSM1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99533519; called by muse, mutect2
- ACSM2B | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1209967180, COSV61660376; called by muse, mutect2, varscan2
- ACTL7A | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV61777313; called by mutect2, varscan2
- ACTRT3 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100377363, COSV57755498; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY9 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.926); catalogued as COSV53582618; called by muse, mutect2
- AFTPH | c.1772A>G p.Q591R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99481318; called by muse, mutect2, varscan2
- AGBL4 | c.1267+2T>A p.X423_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV61896431; called by muse, mutect2, varscan2
- AKAP12 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV53583612; called by muse, mutect2
- ALPP | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); catalogued as COSV67398404; called by muse, mutect2
- ANGPT2 | c.509T>C p.L170S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100291261; called by muse, mutect2
- ANGPTL1 | c.1333T>C p.C445R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99328426; called by muse, varscan2
- ANK3 | c.10678C>T p.R3560W | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs777899600, COSV55085990; called by mutect2, varscan2
- ANKRD30A | c.1515A>C p.K505N (on ENST00000611781; = p.K449N on NM_052997.2) | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV64612384; called by muse, mutect2
- ANKRD45 | c.434G>T p.R145M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100322525, COSV60962770; called by mutect2, varscan2
- APEX2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs868705455, COSV58190428; called by muse, mutect2, varscan2
- ARGLU1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 31/411 reads (8%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.947); catalogued as COSV101033654; called by muse, mutect2
- ARHGAP6 | c.2785G>A p.A929T (on ENST00000337414 / NM_013427.3; = p.A726T on NM_013423.3) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.091); catalogued as rs868368550, COSV57304508; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPHD2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV53221215; called by muse, mutect2, varscan2
- ASPM | c.9896T>C p.I3299T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54140429; called by muse, varscan2
- ASTN1 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746195703, COSV62504346; called by mutect2, varscan2
- ASXL1 | c.4520C>T p.A1507V | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs375101983, COSV60106582; called by muse, mutect2, varscan2
- ASXL2 | c.755G>T p.R252I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV99712184; called by mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 26/208 reads (13%) | catalogued as rs866490133; called by mutect2, varscan2
- ATCAY | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs201501328, COSV100009084; called by mutect2, varscan2
- ATP1A4 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1367205154, COSV63628897; called by muse, mutect2, varscan2
- ATP2B3 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV54864089; called by muse, mutect2, varscan2
- ATP2B3 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782075864, COSV54845442, COSV99685266; called by muse, mutect2
- ATP8A1 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100047503; called by muse, varscan2
- ATP9B | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV56946532; called by muse, mutect2, varscan2
- AVL9 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141983074; called by muse, mutect2, varscan2
- BBS7 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 21/208 reads (10%) | catalogued as rs151275562, CM111650; called by muse, mutect2, varscan2
- BCL9 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.11); catalogued as COSV99325998; called by muse, mutect2, varscan2
- BMERB1 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV55513446; called by muse, mutect2, varscan2
- BMP7 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV67783064; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRF2 | c.1121del p.P374Lfs*16 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | catalogued as rs1367539082; called by mutect2, pindel, varscan2
- BTAF1 | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56440301; called by muse, mutect2, varscan2
- C1RL | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs753114917, COSV56927046; called by muse, mutect2, varscan2
- CA2 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53408614; called by muse, mutect2
- CARNS1 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV57055698; called by muse, mutect2
- CAVIN2 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1218345828, COSV58424152; called by muse, mutect2
- CBLIF | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57240694; called by muse, mutect2, varscan2
- CCDC122 | c.616del p.T206Lfs*14 | Frame Shift Del (DEL) | VAF 14/141 reads (10%) | catalogued as rs764929517; called by mutect2, pindel, varscan2
- CCDC180 | c.1866dup p.L623Tfs*8 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | catalogued as rs1564155733; called by mutect2, pindel, varscan2
- CCDC80 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99245418; called by muse, mutect2
- CD63 | c.139del p.A47Lfs*37 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as COSV57676923; called by mutect2, pindel, varscan2
- CD96 | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs140727933; called by muse, mutect2, varscan2
- CDH6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs777622672, COSV54064764; called by muse, mutect2, varscan2
- CDH8 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765500932, COSV54858415, COSV54909666; called by mutect2, varscan2
- CEMIP2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as rs1473330533, COSV65488192, COSV65489989; called by muse, mutect2, varscan2
- CEP170 | c.3588A>T p.K1196N | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100318026; called by muse, mutect2
- CEP68 | c.425_427del p.T142del | In Frame Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs775634157; called by mutect2, pindel, varscan2
- CEP95 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568127539, COSV101616349; called by muse, mutect2, varscan2
- CFAP36 | c.599A>T p.N200I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59117436, COSV59119596; called by muse, mutect2, varscan2
- CFAP70 | c.2801T>C p.V934A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100161136; called by muse, mutect2
- CHAF1A | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV56676994; called by muse, mutect2
- CLEC12B | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58864664; called by muse, mutect2, varscan2
- CLEC1B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753263519, COSV53726856; called by muse, mutect2, varscan2
- CLSTN3 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769640907, COSV56935057; called by muse, mutect2
- CLUH | c.1943C>T p.S648F (on ENST00000435359; = p.S686F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs746331794, COSV101425921; called by mutect2, varscan2
- CNNM4 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs367842804; ClinVar: uncertain significance; called by mutect2, varscan2
- CNP | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as rs782078035, COSV57270673; called by muse, varscan2
- CNTNAP2 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); catalogued as rs1012333307, COSV62154521; called by muse, mutect2, varscan2
- CNTRL | c.3697C>G p.Q1233E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53054480; called by mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs374805044; called by mutect2, varscan2
- COL27A1 | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100621387; called by muse, mutect2, varscan2
- COL27A1 | c.3476G>A p.G1159D | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs753609873, COSV61931405; called by mutect2, varscan2
- CPXCR1 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV52164804; called by muse, mutect2, varscan2
- CUBN | c.10438T>C p.S3480P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV100913693; called by muse, varscan2
- CUX2 | c.1736A>G p.Y579C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55650166; called by muse, mutect2
- DBNDD2 | c.466A>C p.N156H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61919513; called by muse, mutect2, varscan2
- DCLK2 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | catalogued as COSV99652861; called by muse, mutect2, varscan2
- DHX33 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs749610314, COSV56579869; called by mutect2, varscan2
- DLC1 | c.2300C>T p.A767V (on ENST00000276297 / NM_001348081.2; = p.A330V on NM_006094.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV52297312; called by muse, mutect2
- DNAH10 | c.11768T>C p.M3923T (on ENST00000409039; = p.M3862T on NM_207437.3) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV69004007; called by muse, mutect2, varscan2
- DNAH10 | c.12479G>A p.R4160H (on ENST00000409039; = p.R4099H on NM_207437.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767154529, COSV68989788, COSV68992283; called by muse, mutect2
- DNAH3 | c.7354G>A p.A2452T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs181641902, COSV54520286, COSV99771160; called by muse, mutect2, varscan2
- DNAH8 | c.7471C>A p.P2491T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100547382; called by muse, mutect2, varscan2
- DPP3 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1266213161; called by muse, mutect2
- DROSHA | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60780026; called by muse, mutect2
- DST | c.17223del p.K5741Nfs*2 (on ENST00000361203 / NM_001374722.1; = p.K3438Nfs*2 on NM_015548.5) | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs756726565; called by mutect2, varscan2
- DST | c.13902G>T p.E4634D (on ENST00000361203 / NM_001374722.1; = p.E2222D on NM_015548.5) | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.888); catalogued as COSV55045288; called by muse, mutect2
- E2F7 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs779479853, COSV59739166; called by muse, mutect2, varscan2
- EBF2 | c.1721del p.P574Rfs*20 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as COSV101282098, COSV68778006; called by mutect2, pindel
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as rs369293935; called by mutect2, varscan2
- EHD4 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); catalogued as rs770079590, COSV55004816; called by mutect2, varscan2
- ELK1 | c.1148G>C p.S383T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55954930; called by muse, mutect2, varscan2
- ENAM | c.1553A>G p.K518R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV101253370; called by muse, mutect2
- EPHA5 | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV56678764; called by muse, mutect2, varscan2
- ERBB4 | c.1757G>A p.G586D | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53552311; called by muse, mutect2
- ERCC6 | c.2460A>C p.K820N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV100876316; called by muse, mutect2
- ESAM | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV54037132; called by muse, mutect2
- EVC2 | c.2251C>A p.L751M | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as COSV100187121; called by muse, mutect2
- EXD3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs200247361; called by muse, mutect2
- F9 | c.165T>A p.F55L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as CD910503, COSV54382757; called by muse, mutect2, varscan2
- FAM111B | c.1372A>G p.S458G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV59113957; called by muse, mutect2, varscan2
- FAM135B | c.2077A>T p.S693C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52757460; called by muse, mutect2
- FAM171B | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs145285890, COSV59004840; called by mutect2, varscan2
- FAM200A | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV68809114; called by muse, mutect2, varscan2
- FANCA | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99235427; called by muse, mutect2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, pindel, varscan2
- FCGBP | c.11024G>A p.G3675D | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442045444; called by muse, mutect2
- FCGR1A | c.1034G>A p.R345K | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.438); catalogued as COSV64986181; called by muse, mutect2, varscan2
- FER1L5 | c.5762C>A p.P1921H (on ENST00000623019; = p.P1885H on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53844424; called by muse, mutect2
- FGD4 | c.2041del p.Q681Rfs*31 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs1060501904, COSV56781342; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- FGF16 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV71546323; called by muse, mutect2, varscan2
- FLG | c.8645G>T p.R2882M | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.369); catalogued as rs1280164373, COSV64236797, COSV64251264; called by muse, mutect2, varscan2
- FLG | c.4574A>G p.Q1525R | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1557877601, COSV64251269; called by mutect2, varscan2
- FLT1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as rs1337622453, COSV99169286; called by muse, mutect2, varscan2
- FOCAD | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753108162, COSV58094816; called by mutect2, varscan2
- FRY | c.4982C>T p.A1661V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs375793201; called by mutect2, varscan2
- GABRA6 | c.1318T>C p.Y440H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50898049; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GBX2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103638; called by muse, mutect2
- GFM2 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV57193791; called by muse, mutect2
- GLDC | c.1811A>G p.E604G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100394685; called by muse, mutect2, varscan2
- GLIPR1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328785925, COSV56993255; called by muse, varscan2
- GLS | c.1853+2T>G p.X618_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as COSV57845608; called by muse, varscan2
- GNA14 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100502853; called by muse, mutect2
- GPC2 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs752689029, COSV52786844; called by muse, mutect2, varscan2
- GPM6B | c.292T>C p.F98L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV57425103; called by muse, mutect2, varscan2
- GPR143 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.036); catalogued as COSV101102321; called by muse, mutect2
- GRK6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62682576; called by muse, mutect2
- GTDC1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762033509, COSV53999277; called by mutect2, varscan2
- GUCY2C | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV99664248; called by muse, mutect2, varscan2
- HAT1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51366750; called by muse, mutect2, varscan2
- HBS1L | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779153204, COSV63202896; called by mutect2, varscan2
- HDAC2 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.423); catalogued as COSV64039824; called by muse, mutect2, varscan2
- HEATR1 | c.4291G>A p.A1431T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100857819; called by muse, mutect2, varscan2
- HGSNAT | c.372G>A p.R124= | Splice Region (SNP) | VAF 7/74 reads (9%) | catalogued as COSV101108371; called by muse, mutect2
- HIC1 | c.199G>A p.A67T (on ENST00000322941 / NM_001098202.1; = p.A48T on NM_006497.4) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53973806; called by muse, mutect2
- HJURP | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as COSV64979691; called by muse, mutect2, varscan2
- HLA-B | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV101318289; called by muse, mutect2
- HM13 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59436296; called by muse, mutect2
- IKZF1 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58792511; called by muse, mutect2
- IL10RB | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs1288109259, COSV99270221; called by muse, mutect2, varscan2
- IL15 | c.428dup p.N143Kfs*3 | Frame Shift Ins (INS) | VAF 12/114 reads (11%) | catalogued as rs1345777588; called by mutect2, varscan2
- IL18R1 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV52122719; called by muse, mutect2
- INSR | c.101-2A>G p.X34_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV57174719; called by muse, mutect2, varscan2
- IRAG1 | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101351821; called by muse, mutect2
- ITGA6 | c.1993T>C p.C665R (on ENST00000442250; = p.C626R on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51282230; called by muse, mutect2
- ITLN2 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63538351; called by muse, mutect2, varscan2
- ITPR1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV57007191; called by muse, mutect2, varscan2
- KAT14 | c.299A>T p.N100I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as COSV66607199, COSV66609522; called by muse, mutect2, varscan2
- KCND2 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58607425; called by muse, mutect2, varscan2
- KCNH8 | c.2176T>C p.S726P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100111173; called by mutect2, varscan2
- KCNJ13 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs752305262, COSV52085551; called by mutect2, varscan2
- KCNQ2 | c.622A>T p.M208L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as CM033388, COSV100610642; called by muse, mutect2
- KDM3B | c.3046+1G>A p.X1016_splice | Splice Site (SNP) | VAF 14/84 reads (17%) | catalogued as COSV58696193; called by muse, mutect2, varscan2
- KDSR | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV58508445; called by muse, mutect2
- KIAA2013 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV64861315; called by muse, mutect2, varscan2
- KIF21B | c.4753G>A p.G1585S (on ENST00000422435 / NM_001252100.2; = p.G1572S on NM_017596.4) | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59768176; called by muse, varscan2
- KIF2C | c.918C>A p.N306K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100945899; called by mutect2, varscan2
- KLHL7 | c.1390C>G p.L464V (on ENST00000339077 / NM_001031710.3; = p.L416V on NM_018846.5) | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100178489; called by muse, mutect2
- KMT2D | c.8915A>G p.E2972G | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56493258; called by muse, mutect2, varscan2
- KPNA1 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100724437; called by muse, mutect2
- KRT80 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1355993193, COSV57552160; called by muse, mutect2, varscan2
- KRTAP4-5 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV100576853; called by muse, mutect2
- KTN1 | c.3302dup p.A1102Gfs*15 (on ENST00000395314 / NM_001271014.2; = p.A1073Gfs*15 on NM_004986.4) | Frame Shift Ins (INS) | VAF 19/111 reads (17%) | catalogued as rs1438655793; called by mutect2, varscan2
- LARGE1 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100506547; called by muse, mutect2
- LATS2 | c.2308T>C p.F770L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66879423; called by muse, mutect2, varscan2
- LEMD3 | c.1836G>T p.Q612H | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100384690; called by muse, mutect2, varscan2
- LIN28B | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs76912525, COSV61498203; called by mutect2, varscan2
- LRP2 | c.6739T>C p.Y2247H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.823); catalogued as COSV99790624; called by muse, mutect2, varscan2
- LYST | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1037862310, COSV101090441; called by muse, mutect2
- MACF1 | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as rs369062828; called by muse, mutect2, varscan2
- MACF1 | c.17599A>G p.N5867D (on ENST00000372915; = p.N3909D on NM_012090.5) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | catalogued as COSV99247340; called by muse, mutect2
- MAP3K4 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV62334901, COSV62339466; called by muse, mutect2, varscan2
- MBNL3 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100898536; called by muse, mutect2, varscan2
- MDH1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1415236992, COSV51863995; called by muse, mutect2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs750092100; called by mutect2, varscan2
- MGAT3 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57869063; called by muse, mutect2
- MGAT4C | c.336del p.G113Efs*20 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs1347429614; called by mutect2, pindel, varscan2
- MIB2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs1250293210, COSV61755226; called by muse, mutect2
- MKI67 | c.4012G>A p.E1338K | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.344); catalogued as COSV64074975, COSV64077509; called by muse, mutect2
- MMP3 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1443827949, COSV55408490; called by muse, mutect2
- MRPL14 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs138947067; called by muse, mutect2, varscan2
- MSN | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100814269, COSV64305704; called by muse, mutect2, varscan2
- MSX2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201449653, COSV53327472; called by muse, mutect2, varscan2
- MUC4 | c.15419G>T p.G5140V (on ENST00000463781 / NM_018406.7; = p.G904V on NM_004532.6) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as COSV57806255; called by muse, mutect2, varscan2
- MUC5B | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV71592078; called by muse, mutect2, varscan2
- MYCBP2 | c.2396C>A p.P799H (on ENST00000357337; = p.P837H on NM_015057.5) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62042268; called by muse, mutect2, varscan2
- MYO16 | c.3490C>G p.R1164G | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62744176, COSV62763794; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 34/213 reads (16%) | catalogued as rs763929397; called by mutect2, varscan2
- NAA15 | c.2554A>G p.N852D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.079); catalogued as COSV99649992; called by muse, mutect2, varscan2
- NAALADL2 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV70296746; called by muse, mutect2, varscan2
- NCOR2 | c.3998G>A p.R1333H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs562298385, COSV62305880; called by muse, mutect2, varscan2
- NDUFB9 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1156454853, COSV52674103; called by muse, mutect2, varscan2
- NEDD4L | c.1457A>G p.N486S (on ENST00000400345 / NM_001144967.3; = p.N466S on NM_015277.6) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs965302278; called by muse, mutect2
- NENF | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65341525; called by muse, mutect2
- NOTCH1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.574); catalogued as rs1238603957, COSV53101105; called by muse, mutect2, varscan2
- NOX1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772834730, COSV99471764; called by mutect2, varscan2
- NUDT17 | c.935A>G p.K312R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV100566885; called by muse, mutect2, varscan2
- NUP153 | c.3895T>G p.S1299A | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100020942, COSV50454747; called by muse, mutect2
- OLFML2A | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV56582012; called by muse, mutect2, varscan2
- OR10H5 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV58279410; called by muse, mutect2, varscan2
- OR13C4 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV52928765; called by muse, mutect2, varscan2
- OR1L8 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as COSV59187600; called by muse, mutect2, varscan2
- OR2A5 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs902648333, COSV101278875; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 12/136 reads (9%) | catalogued as rs1268396241; called by mutect2, pindel
- ORC1 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs537583215, COSV65365412; called by mutect2, varscan2
- PAK1 | c.477+2T>C p.X159_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV53702314; called by muse, mutect2, varscan2
- PAK5 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs559966028, COSV62025299, COSV62039210; called by mutect2, varscan2
- PAPPA | c.1685A>G p.H562R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100075625; called by muse, mutect2
- PATZ1 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1222871755, COSV53231582; called by muse, mutect2
- PCYT1A | c.838_840del p.E280del | In Frame Del (DEL) | VAF 20/146 reads (14%) | catalogued as rs771425372; called by pindel, varscan2
- PDE3B | c.2264G>T p.R755L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56384876; called by muse, mutect2, varscan2
- PDE4DIP | c.6871C>T p.R2291* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as rs782089136, COSV57694517; called by muse, mutect2, varscan2
- PDZD2 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs1181686491, COSV56875332; called by muse, mutect2, varscan2
- PHACTR1 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 10/107 reads (9%) | catalogued as COSV60684444; called by muse, varscan2
- PHOX2A | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53357942; called by muse, mutect2
- PKHD1 | c.3487G>A p.A1163T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs755422798, COSV100584834; called by mutect2, varscan2
- PLA2G4A | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100820767, COSV66554022; called by muse, mutect2, varscan2
- PLCXD1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs141404099, COSV58205961; called by muse, mutect2, varscan2
- PLEC | c.9307C>T p.Q3103* (on ENST00000322810 / NM_201380.4; = p.Q2993* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as rs1554683453, COSV100519813; called by muse, mutect2
- PLEKHG6 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs773846283, COSV50616701; called by muse, mutect2, varscan2
- POLRMT | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs751211087, COSV52119404; called by muse, mutect2, varscan2
- POMT1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.798); catalogued as COSV100586619; called by muse, mutect2, varscan2
- PPARGC1A | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.321); catalogued as COSV53534419; called by muse, mutect2, varscan2
- PRKDC | c.12272C>T p.A4091V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1328372525, COSV58066362; called by muse, mutect2, varscan2
- PRTG | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101221514; called by muse, mutect2, varscan2
- PRUNE2 | c.3313C>T p.R1105W | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs778837245, COSV65047321; called by mutect2, varscan2
- RADX | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV100998933; called by muse, mutect2
- RBM38 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs754322312, COSV100654924, COSV100654943; called by mutect2, varscan2
- REV3L | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV62624335; called by muse, mutect2
- RHBDL3 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99284006; called by muse, mutect2, varscan2
- RIPOR3 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567479170, COSV50387435; called by muse, mutect2, varscan2
- RPGRIP1L | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50920017; called by muse, mutect2, varscan2
- RPTOR | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1463759489, COSV60802770; called by muse, mutect2
- RTL3 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100330036, COSV58186216; called by muse, varscan2
- RUNX1T1 | c.662C>T p.A221V (on ENST00000265814 / NM_001198628.1; = p.A194V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV56165647; called by muse, mutect2, varscan2
- RXRG | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs371364035; called by mutect2, varscan2
- RYR1 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757261781, COSV62106653; called by mutect2, varscan2
- RYR3 | c.3311C>T p.A1104V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs1262972889, COSV101214981; called by muse, varscan2
- SBF1 | c.5537C>A p.P1846H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53299694, COSV99324405; called by muse, mutect2, varscan2
- SEC24D | c.2819T>A p.I940N | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54885648; called by muse, mutect2
- SEL1L2 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV99534072; called by muse, mutect2
- SEZ6 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100253646; called by muse, varscan2
- SH3BGRL2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs983770941, COSV63963797; called by muse, mutect2, varscan2
- SLC1A7 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs371287501; called by mutect2, varscan2
- SLC25A36 | c.795del p.Q266Rfs*19 (on ENST00000324194 / NM_001104647.3; = p.Q265Rfs*19 on NM_018155.3) | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs1559818665; called by mutect2, pindel, varscan2
- SLC26A3 | c.2007+2T>C p.X669_splice | Splice Site (SNP) | VAF 15/81 reads (19%) | catalogued as rs764591347, COSV60643208; called by muse, mutect2, varscan2
- SLC2A11 | c.1013G>A p.R338H (on ENST00000345044 / NM_001024938.4; = p.R345H on NM_030807.5) | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372590867; called by muse, mutect2, varscan2
- SLC39A10 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62769972; called by muse, mutect2
- SLC5A6 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs947392204, COSV60161724; called by muse, mutect2, varscan2
- SLC7A2 | c.1361C>T p.S454L (on ENST00000494857 / NM_001370338.1; = p.S493L on NM_003046.6) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs549251912, COSV50258142; called by mutect2, varscan2
- SNTA1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs754648214, COSV54128392; ClinVar: uncertain significance; called by mutect2, varscan2
- SNW1 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV55057381; called by muse, mutect2
- SOS1 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67677972; called by muse, mutect2
- SPARCL1 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99216008; called by muse, mutect2, varscan2
- STAB2 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206167637, COSV66348403; called by muse, mutect2
- STAB2 | c.7150A>G p.S2384G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs140732585; called by mutect2, varscan2
- STX19 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV57402425; called by muse, mutect2, varscan2
- TARS2 | c.364T>G p.F122V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV64697129; called by mutect2, varscan2
- TBC1D10B | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs142710856, COSV99977081; called by muse, mutect2, varscan2
- TBX6 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661838; called by muse, mutect2
- TCAIM | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs767273410, COSV61243040; called by muse, mutect2, varscan2
- TESK2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1227764599, COSV59158112; called by muse, mutect2, varscan2
- TMUB2 | c.431C>A p.P144H (on ENST00000538716 / NM_001353177.2; = p.P124H on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV60230072; called by muse, mutect2
- TNC | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs770789816, COSV60791519; called by mutect2, varscan2
- TNS2 | c.3305G>A p.S1102N (on ENST00000314250 / NM_170754.4; = p.S1112N on NM_015319.2) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56854010; called by muse, mutect2
- TNXB | c.6236C>T p.P2079L (on ENST00000647633; = p.P1832L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs768187269, COSV64490405; called by muse, mutect2
- TRERF1 | c.3497T>A p.V1166D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs772201320, COSV61667388; called by mutect2, varscan2
- TRIM25 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100381221; called by muse, mutect2, varscan2
- TRIP12 | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV52273976; called by muse, mutect2, varscan2
- TRMU | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1569082148, COSV51990006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPC4 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59022040; called by muse, mutect2, varscan2
- TRPM1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99856844; called by muse, mutect2
- TSPYL2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs376609801; called by muse, mutect2
- TTN | c.77845G>A p.A25949T (on ENST00000591111; = p.A18525T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | PolyPhen benign (0.02); catalogued as COSV60397255; called by muse, mutect2, varscan2
- TTN | c.31893del p.V10632Yfs*16 (on ENST00000591111; = p.V9705Yfs*16 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | catalogued as COSV100623563; called by mutect2, pindel, varscan2
- TTN | c.29027G>A p.R9676Q (on ENST00000591111; = p.R8749Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | PolyPhen benign (0.021); catalogued as rs575360239, COSV60144489; called by muse, mutect2, varscan2
- TTN | c.8839G>A p.D2947N (on ENST00000591111; = p.D2901N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | PolyPhen probably damaging (0.998); catalogued as COSV60397315; called by muse, mutect2
- TUBGCP3 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1005904077, COSV56192039; called by muse, mutect2, varscan2
- UBE2O | c.1005-1G>T p.X335_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100085128; called by muse, mutect2
- UBE3D | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52758097; called by muse, mutect2, varscan2
- UBQLN4 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1284905343, COSV64150667; called by muse, mutect2
- ULK2 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs751585231, COSV64449015, COSV64449219; called by mutect2, varscan2
- UNC5D | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54769694; called by muse, mutect2
- VEZT | c.1434T>G p.I478M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99704380; called by muse, mutect2, varscan2
- VPS33A | c.1376del p.G459Afs*86 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | catalogued as rs1357715083, COSV57357082; called by mutect2, pindel, varscan2
- VWF | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV99780492; called by muse, mutect2
- WDR33 | c.1045A>C p.S349R | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100460797; called by muse, mutect2, varscan2
- WIPF3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV54209865; called by muse, mutect2
- WNK1 | c.3391C>T p.R1131* (on ENST00000315939 / NM_018979.4; = p.R884* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV60047557; called by muse, mutect2, varscan2
- ZBTB3 | c.871T>C p.S291P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101189014; called by muse, mutect2
- ZC3H13 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs375011338; called by mutect2, varscan2
- ZC3H7B | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs778231641, COSV100687887; called by mutect2, varscan2
- ZEB1 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs754135071, COSV58042268, COSV58050747; called by mutect2, varscan2
- ZFHX3 | c.11104A>T p.R3702* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV51739267; called by muse, mutect2, varscan2
- ZFYVE19 | c.752A>G p.Q251R (on ENST00000355341 / NM_001077268.2; = p.Q241R on NM_032850.5) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV99591917; called by muse, mutect2
- ZFYVE27 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61747472; called by muse, mutect2
- ZNF112 | c.2372G>A p.R791H (on ENST00000337401 / NM_001083335.2; = p.R785H on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.097); catalogued as rs564476950, COSV61619923; called by muse, mutect2, varscan2
- ZNF514 | c.1195del p.T399Pfs*21 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs755697811; called by mutect2, varscan2
- ZNF517 | c.390del p.H131Tfs*95 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as rs746799858; called by mutect2, pindel
- ZNF526 | c.1148C>A p.T383N | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55901025; called by muse, mutect2
- ZNF568 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100451472; called by muse, mutect2, varscan2
- ZNF74 | c.1792G>A p.V598M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.009); catalogued as rs548640768, COSV62622530; called by mutect2, varscan2
- ZNF791 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV58483125; called by muse, mutect2, varscan2
- ZNF99 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777942700, COSV101233996; called by muse, mutect2, varscan2
- APOBEC4 | c.633del p.Q212Sfs*4 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | called by mutect2, pindel
- BOC | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- BUB1 | c.2455dup p.V819Gfs*61 | Frame Shift Ins (INS) | VAF 14/136 reads (10%) | called by mutect2, pindel
- C21orf58 | c.540del p.T181Rfs*41 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, varscan2
- C2orf73 | c.622del p.T208Qfs*11 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- CHD9 | c.7621dup p.R2541Kfs*9 (on ENST00000398510 / NM_001382353.1; = p.R2525Kfs*9 on NM_025134.7) | Frame Shift Ins (INS) | VAF 16/157 reads (10%) | called by mutect2, pindel, varscan2
- CKAP2 | c.883del p.T295Qfs*14 (on ENST00000378037 / NM_001098525.2; = p.T294Qfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- CLCN4 | c.2043del p.E682Sfs*10 | Frame Shift Del (DEL) | VAF 19/114 reads (17%) | called by mutect2, pindel, varscan2
- CNOT3 | c.1373del p.P458Lfs*45 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel, varscan2
- DNAH8 | c.2556del p.A853Lfs*9 | Frame Shift Del (DEL) | VAF 13/132 reads (10%) | called by mutect2, pindel, varscan2
- DOCK5 | c.4705-3_4706delinsAGGCT p.X1569_splice | Splice Site (ONP) | VAF 5/56 reads (9%) | called by pindel, varscan2*
- FCGBP | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- GAS2L2 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GGA2 | c.661-2dup p.X221_splice | Splice Site (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- GLS | c.1085dup p.L362Ffs*3 | Frame Shift Ins (INS) | VAF 12/138 reads (9%) | called by mutect2, pindel
- GPR151 | c.984dup p.P329Tfs*20 | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- GRM6 | c.929dup p.A311Sfs*30 | Frame Shift Ins (INS) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- GUCY2F | c.957dup p.E320Rfs*16 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- HNRNPU | c.883_885del p.E295del (on ENST00000283179; = p.E357del on NM_004501.3) | In Frame Del (DEL) | VAF 14/148 reads (9%) | called by pindel, varscan2
- HYOU1 | c.1952del p.K651Rfs*46 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 9/94 reads (10%) | called by mutect2, pindel, varscan2
- KCNJ11 | c.306del p.S103Afs*27 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- LILRB3 | c.888C>A p.C296* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | called by muse, varscan2
- LRIG3 | c.2840-2dup p.X947_splice | Splice Site (INS) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- LRP2 | c.1603dup p.E535Gfs*3 | Frame Shift Ins (INS) | VAF 11/105 reads (10%) | called by mutect2, pindel, varscan2
- MACROH2A1 | c.395del p.P132Qfs*66 (on ENST00000510038; = p.P132Qfs*65 on NM_004893.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/137 reads (12%) | called by mutect2, pindel, varscan2
- MAPK8IP1 | c.1928del p.N643Tfs*91 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- MBD5 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- MCM10 | c.718del p.E240Kfs*26 (on ENST00000484800 / NM_182751.3; = p.E239Kfs*26 on NM_018518.5) | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- MKS1 | c.599del p.P200Lfs*29 | Frame Shift Del (DEL) | VAF 11/129 reads (9%) | called by mutect2, pindel
- MUC16 | c.10894dup p.H3632Pfs*17 | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- MYLK | c.3377del p.P1126Qfs*8 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by mutect2, pindel
- MYO18B | c.429del p.F144Sfs*5 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- NBEA | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPLOC4 | c.747del p.F249Lfs*88 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel
- NSD2 | c.2966del p.P989Hfs*8 | Frame Shift Del (DEL) | VAF 21/192 reads (11%) | called by mutect2, pindel, varscan2
- NUDT22 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2
- OSBPL6 | c.327del p.F109Lfs*8 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | called by mutect2, varscan2
- PLCB2 | c.512del p.F171Sfs*43 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- POLB | c.504del p.V169Wfs*27 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- POLR3A | c.4025G>A p.G1342E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEA | c.1146A>C p.E382D (on ENST00000519951 / NM_001005365.2; = p.E336D on NM_001002920.1) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PRELID3B | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTBP2 | c.1377dup p.P460Sfs*10 (on ENST00000426398 / NM_001300986.2; = p.P452Sfs*10 on NM_021190.4) | Frame Shift Ins (INS) | VAF 17/122 reads (14%) | called by mutect2, pindel, varscan2
- PTN | c.123del p.V42* | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, varscan2
- PYM1 | c.405del p.T136Qfs*19 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 14/145 reads (10%) | called by mutect2, pindel, varscan2
- REST | c.1311G>C p.L437F | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2
- ROS1 | c.3740del p.N1247Mfs*14 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- RPN2 | c.587del p.G196Afs*41 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- SPACA5B | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 43/635 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.107); called by muse, mutect2
- TAF1 | c.2436del p.A813Pfs*14 (on ENST00000373790 / NM_138923.4; = p.A834Pfs*14 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- TBC1D1 | c.63dup p.G22Wfs*25 | Frame Shift Ins (INS) | VAF 8/87 reads (9%) | called by mutect2, pindel
- TENM2 | c.4571del p.N1524Tfs*20 (on ENST00000518659 / NM_001122679.2; = p.N1285Tfs*20 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, varscan2
- TLE2 | c.744del p.S249Afs*43 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- TRAPPC12 | c.1802del p.K601Sfs*9 | Frame Shift Del (DEL) | VAF 20/218 reads (9%) | called by mutect2, pindel
- TREH | c.340del p.Q114Sfs*29 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- TRIM2 | c.1474del p.V492* (on ENST00000437508; = p.V519* on NM_015271.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/169 reads (14%) | called by mutect2, pindel, varscan2
- UBN2 | c.3572del p.G1191Efs*28 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- ZBTB24 | c.705del p.D236Mfs*74 | Frame Shift Del (DEL) | VAF 24/248 reads (10%) | called by mutect2, pindel
- ADAMTSL4 | c.798G>A p.T266= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs587626697, COSV55008769; called by muse, mutect2
- AHCTF1 | c.4875C>T p.S1625= (on ENST00000366508; = p.S1599= on NM_015446.5) | Silent (SNP) | VAF 27/285 reads (9%) | catalogued as COSV100404553; called by muse, mutect2
- ANKRD55 | c.882G>T p.R294= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100591730; called by muse, mutect2, varscan2
- ASB2 | c.606C>T p.D202= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV60114783; called by muse, mutect2, varscan2
- ASTN2 | c.2364G>A p.V788= (on ENST00000313400 / NM_001365069.1; = p.V737= on NM_014010.5) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs747783100, COSV57822736; called by mutect2, varscan2
- ATP5F1A | c.657C>T p.T219= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV56360951; called by muse, mutect2, varscan2
- BCL9 | c.3435G>A p.Q1145= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99325999; called by muse, mutect2
- C3 | c.1803C>T p.G601= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs370859261, COSV55582663; called by mutect2, varscan2
- CACNA1B | c.4263G>A p.E1421= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV53152320; called by muse, mutect2, varscan2
- CACNA1E | c.2739G>A p.R913= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV62384898; called by muse, mutect2
- CCDC62 | c.202C>T p.L68= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1352138455, COSV53437716; called by muse, mutect2, varscan2
- CCL23 | c.222C>A p.S74= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- CCNT1 | c.1527G>A p.K509= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs1420920764, COSV56066417; called by muse, mutect2, varscan2
- CDHR3 | c.90T>C p.N30= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100488961; called by muse, mutect2
- CEP120 | c.1269A>T p.V423= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV60269103; called by muse, mutect2
- CES3 | c.111C>T p.D37= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs747127368, COSV100310073; called by mutect2, varscan2
- CHD7 | c.6693T>C p.S2231= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV71115246; called by muse, mutect2, varscan2
- CNGA4 | c.882C>T p.H294= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV66007213; called by mutect2, varscan2
- CNTROB | c.2070A>G p.G690= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100972796; called by muse, mutect2
- COL18A1 | c.3765C>T p.G1255= (on ENST00000359759 / NM_130444.3; = p.G1020= on NM_030582.4) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs756624877, COSV60594444; called by muse, mutect2, varscan2
- DLGAP3 | c.1995C>T p.D665= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99333291; called by muse, mutect2
- DNAH3 | c.3537C>T p.N1179= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs768318201, COSV54516365; called by muse, mutect2, varscan2
- DOK4 | c.708G>A p.R236= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV54674642; called by muse, mutect2
- EIF3A | c.3882C>T p.D1294= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV64963789; called by muse, mutect2, varscan2
- EMILIN1 | c.156A>G p.P52= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs750223152, COSV66695577; called by mutect2, varscan2
- EPM2A | c.822C>T p.T274= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs763812238, COSV62298113; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXL4 | c.453C>T p.V151= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV57750471; called by muse, mutect2, varscan2
- FN3K | c.678C>T p.D226= | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as rs1041828437, COSV100333410; called by muse, mutect2, varscan2
- GEMIN4 | c.909C>A p.T303= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV56747828; called by mutect2, varscan2
- GPR108 | c.1458G>T p.L486= (on ENST00000264080 / NM_001080452.1; = p.L244= on NM_020171.2) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV51188400; called by muse, mutect2
- GTF2E1 | c.288T>C p.Y96= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV52206650; called by muse, mutect2, varscan2
- GTF3C3 | c.2301T>A p.P767= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- HECTD4 | c.12672C>T p.S4224= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV66401074; called by muse, mutect2
- HTR2C | c.813G>A p.T271= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52203586, COSV52204062; called by muse, mutect2, varscan2
- IKBKE | c.1260C>T p.G420= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs374782915, COSV65627215; called by muse, mutect2, varscan2
- IRF3 | c.276A>G p.L92= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV55864818; called by muse, mutect2
- KIF15 | c.171G>A p.T57= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs758234349, COSV58165272; called by muse, mutect2, varscan2
- KLHL10 | c.1221G>A p.E407= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs782189079, COSV53175353; called by muse, mutect2
- KRT34 | c.372G>A p.A124= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs761821120, COSV67449534; called by muse, mutect2, varscan2
- LONP1 | c.2028C>T p.P676= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV61502158; called by muse, mutect2, varscan2
- LRRC23 | c.852C>T p.D284= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs782399146, COSV50387899; called by muse, mutect2, varscan2
- LRRC41 | c.1785A>G p.G595= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV58442790; called by muse, mutect2, varscan2
- MAN2A2 | c.3261C>T p.A1087= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- MAN2B2 | c.2253C>T p.I751= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs779742045, COSV53457391; called by muse, mutect2, varscan2
- MANEAL | c.831T>C p.P277= (on ENST00000373045 / NM_001113482.1; = p.P55= on NM_152496.2) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100203984; called by muse, mutect2
- MFHAS1 | c.2175C>T p.H725= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs767806746, COSV52287535; called by mutect2, varscan2
- MKRN1 | c.1335C>T p.G445= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs777122502, COSV55439131; called by muse, mutect2, varscan2
- MKRN3 | c.162C>A p.G54= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs752040288, COSV58812664; called by muse, mutect2, varscan2
- MMP17 | c.1644A>G p.Q548= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV62181691; called by muse, mutect2, varscan2
- MUC17 | c.5082T>C p.S1694= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60306526; called by muse, mutect2, varscan2
- MYO3B | c.2139A>G p.G713= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100512059; called by muse, mutect2, varscan2
- NBEAL2 | c.726G>A p.P242= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1405669215, COSV99437941; called by muse, mutect2
- NCAM2 | c.786C>T p.S262= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV53100045; called by mutect2, varscan2
- NCOA5 | c.330C>T p.Y110= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs747394313, COSV51647911; called by mutect2, varscan2
- NDUFV1 | c.633G>A p.A211= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs368139042; called by muse, mutect2, varscan2
- NEMF | c.1809T>G p.A603= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100027398; called by muse, mutect2, varscan2
- NLRP8 | c.351C>T p.V117= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV52595047; called by muse, mutect2, varscan2
- NSFL1C | c.870C>T p.D290= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs141160175; called by mutect2, varscan2
- NTM | c.345C>T p.C115= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs1387986653, COSV100869752; called by muse, mutect2
- OR11G2 | c.135C>T p.S45= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV62133277; called by muse, mutect2, varscan2
- OR1G1 | c.93C>T p.F31= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs769103320, COSV61030745; called by mutect2, varscan2
- PARP1 | c.1896G>A p.T632= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as rs200966933, COSV64691203; called by mutect2, varscan2
- PCDHA2 | c.2091C>T p.N697= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV65367452; called by muse, mutect2, varscan2
- PIGU | c.1011C>A p.L337= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99466974; called by muse, mutect2
- PINX1 | c.765G>A p.A255= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs780628077, COSV59108553; called by mutect2, varscan2
- PLAG1 | c.804G>A p.P268= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs141511335, COSV57612338; called by mutect2, varscan2
- PLCB2 | c.1213C>T p.L405= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53038809; called by muse, mutect2, varscan2
- POLD1 | c.3106C>T p.L1036= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1207238630, COSV54532896; called by muse, mutect2
- POTEE | c.369C>T p.Y123= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as rs543579375, COSV58237090; called by muse, mutect2, varscan2
- PRH2 | c.198T>C p.N66= | Silent (SNP) | VAF 33/302 reads (11%) | catalogued as COSV67171922; called by muse, mutect2, varscan2
- PRKACB | c.675A>G p.L225= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV65761415; called by muse, mutect2
- PXN | c.1179C>T p.S393= (on ENST00000228307 / NM_001080855.3; = p.S359= on NM_002859.4) | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as COSV57222290; called by muse, mutect2
- RAPGEF2 | c.2691A>G p.L897= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV52434571; called by muse, mutect2, varscan2
- RAVER2 | c.702T>C p.C234= | Silent (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- ROR2 | c.303G>A p.P101= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs113612512, COSV65224169; called by mutect2, varscan2
- RPS6KC1 | c.882C>T p.A294= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs200954000; called by mutect2, varscan2
- SEC61A2 | c.552C>T p.A184= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100036731; called by muse, mutect2, varscan2
- SERPINA9 | c.372C>T p.P124= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100098939; called by muse, mutect2, varscan2
- SLC16A3 | c.1296T>C p.P432= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV58366902; called by muse, mutect2, varscan2
- SLC44A3 | c.156G>A p.S52= (on ENST00000271227 / NM_001114106.3; = p.S4= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1019892007, COSV54734520; called by muse, mutect2, varscan2
- SMARCC2 | c.837T>C p.D279= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV57225870; called by muse, mutect2, varscan2
- SPPL2B | c.417C>T p.P139= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs768990264, COSV101194565, COSV101194656; called by mutect2, varscan2
- SREBF1 | c.2451G>A p.V817= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- TAX1BP1 | c.1146C>T p.N382= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs762624755, COSV55297599; called by muse, mutect2, varscan2
- TLCD3B | c.174C>T p.I58= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1007122415, COSV99662614; called by muse, mutect2, varscan2
- TMCC2 | c.729C>T p.A243= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1282568352, COSV58006910; called by muse, mutect2, varscan2
- TMEM130 | c.1087C>A p.R363= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs142570247, COSV59561389; called by muse, mutect2, varscan2
- TOP3B | c.1953G>A p.T651= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs748637983, COSV64116369; called by muse, mutect2, varscan2
- TRABD2A | c.324C>T p.G108= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs61739498; called by mutect2, varscan2
- TRIM59 | c.354T>G p.G118= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100557587; called by muse, mutect2, varscan2
- TRRAP | c.6309C>T p.R2103= (on ENST00000359863 / NM_001244580.1; = p.R2085= on NM_003496.3) | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs782000637, COSV100723153; called by muse, mutect2
- TSR1 | c.372G>A p.L124= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs1293257685, COSV99280647; called by muse, mutect2, varscan2
- XAB2 | c.2139G>A p.R713= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV50375405; called by muse, mutect2
- YTHDC2 | c.282G>A p.K94= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99363981; called by muse, mutect2, varscan2
- ZNF180 | c.1044T>G p.S348= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99660108; called by muse, mutect2
- ZNF263 | c.663C>T p.D221= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs1178117381, COSV54595574; called by muse, mutect2, varscan2
- ZNF532 | c.930C>A p.A310= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV60175859; called by mutect2, varscan2
- DTWD2 | c.218+13628del | Intron (DEL) | VAF 58/549 reads (11%) | catalogued as rs1303767738; called by mutect2, varscan2
- MIR1251 | n.65C>T | RNA (SNP) | VAF 8/50 reads (16%) | catalogued as rs1431906233; called by muse, mutect2
- OSGIN1 | n.1713C>A | RNA (SNP) | VAF 14/125 reads (11%) | catalogued as COSV59423964; called by mutect2, varscan2
- TPM2 | chr9:35682149 C>T | 3'Flank (SNP) | VAF 8/44 reads (18%) | catalogued as rs1356074198, COSV100253593; called by muse, mutect2
- TUBB7P | n.553G>A | RNA (SNP) | VAF 28/236 reads (12%) | catalogued as rs782281861; called by muse, mutect2, varscan2
- UBAC2 | c.808-11563T>C | Intron (SNP) | VAF 8/76 reads (11%) | catalogued as rs200647652, COSV100854442; called by mutect2, varscan2
